Gene-level copy-number profile of tumor specimen ALCH-B2D6-TTP1-A from ALCHEMIST case ALCH-B2D6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.6 years (25,063 days).
Specimen ALCH-B2D6-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9c12e3ef-28d8-4d37-a188-4d02eb2c7c8e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2D6-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/e877adf8-2744-468f-a1ec-fb9d53876ad5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 4,609; copy number 2: 48,670; copy number 3: 4,228; copy number 4: 334; copy number 5: 70; copy number 6: 76; copy number 7: 110; copy number 8: 42; copy number 9: 55; copy number 10: 75; copy number 11: 22; copy number 13: 25; copy number 14: 33; copy number 16: 10.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:87,194,786–87,194,859, 1 gene (within-gene range 0–2): MIR4771-1.
- chr2:128,236,716–128,318,868, 1 gene: HS6ST1.
- chr3:12,257,801–12,258,460, 1 gene: GSTM5P1.
- chr3:52,455,118–52,524,495, 2 genes (within-gene range 0–2): NISCH, STAB1.
- chr3:126,988,594–127,037,392, 1 gene: PLXNA1.
- chr4:1,009,936–1,028,972, 2 genes: FGFRL1, AC019103.1.
- chr4:2,793,071–2,841,098, 1 gene: SH3BP2.
- chr7:98,211,439–98,252,232, 2 genes: BHLHA15, TECPR1.
- chr10:101,226,195–101,229,794, 1 gene (within-gene range 0–2): LBX1.
- chr12:131,235,511–131,237,523, 1 gene: AC126564.1.
- chr14:103,519,667–103,550,406, 4 genes: CKB, AL133367.1, TRMT61A, RNU7-160P.
- chr14:104,138,723–104,180,894, 1 gene: KIF26A.
- chr16:649,311–709,067, 12 genes (within-gene range 0–1): WDR90, AL022341.2, RHOT2, RHBDL1, LINC02867, Z92544.2, STUB1, JMJD8, WDR24, Z92544.1, FBXL16, Z97653.2.
- chr16:2,047,967–2,089,491, 1 gene (within-gene range 0–1): TSC2.
- chr16:2,090,195–2,090,284, 1 gene (within-gene range 0–1): MIR1225.
- chr17:79,707,176–79,712,317, 2 genes: MIR4739, LINC02078.
- chr19:4,969,113–5,153,598, 1 gene: KDM4B.
- chr19:43,372,742–43,379,123, 1 gene: CD177P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 518 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:169,709,295–170,418,615, 30 genes, copy number 7: SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2.
- chr5:58,198–2,184,820, 75 genes, copy number 6–14 (broad region; genes not listed).
- chr5:3,595,832–5,320,304, 21 genes, copy number 7–16: IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063, AC106799.3, AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1.
- chr5:7,287,924–7,925,398, 14 genes, copy number 8: AC091951.2, AC091951.3, AC091951.1, AC027343.3, LINC02123, AC027343.1, AC027343.2, LINC02142, ADCY2, AC093305.1, C5orf49, MTRR, FASTKD3, AC025174.1.
- chr8:73,670,441–81,284,777, 112 genes, copy number 5–10 (within-gene range 3–10) (broad region; genes not listed).
- chr8:97,775,057–100,336,218, 57 genes, copy number 7–8: LAPTM4B, AP003357.1, AP002906.1, SUMO2P18, RPS23P1, MATN2, RPL30, AP003352.1, SNORA72, RNU6-703P, ERICH5, RIDA, POP1, NIPAL2, RNU6-914P, STK3, AP003355.3, AP003355.1, KCNS2, AP003355.2, RNU6-748P, AP003467.1, AP003467.2, RPL19P14, AC016877.2, MRPL57P7, RN7SKP85, AC016877.3, OSR2, VPS13B-DT, AC016877.1, AC104986.1, VPS13B, AC107909.2, AC107909.1, AP004290.1, AP004289.2, AP004289.1, Y_RNA, MIR599, MIR875, RN7SL350P, AC018442.1, AC018442.2, AC018442.3, COX6C, AC105328.1, RGS22, SNORD77B, AC021590.1, FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A.
- chr8:101,686,542–102,124,907, 1 gene, copy number 13 (within-gene range 3–13): NCALD.
- chr8:101,871,830–102,893,864, 21 genes, copy number 13 (within-gene range 4–13): PDCL3P2, MIR5680, AP001328.1, RRM2B, UBR5-AS1, SUMO2P19, UBR5, AP002907.1, AP002981.1, RNU6ATAC8P, HSPE1P14, RPS12P15, AP002852.1, RNU6-1224P, ODF1, POU5F1P2, KLF10, ADI1P2, GASAL1, AZIN1, AP003696.1.
- chr8:105,826,570–106,752,694, 8 genes, copy number 5 (within-gene range 2–5): AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1.
- chr8:113,950,886–114,791,929, 4 genes, copy number 5–8: Y_RNA, AC064802.1, AC025881.1, CARS1P2.
- chr8:118,189,455–120,050,918, 28 genes, copy number 5: SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277.
- chr8:120,913,065–123,290,503, 35 genes, copy number 5–7: AC068413.1, AC011626.1, RPL35AP19, HAS2, HAS2-AS1, LINC02855, AC037486.1, MRPS36P3, SMILR, LINC01151, AC108136.1, AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2, ZHX2, AC016405.1, AC104316.2, AC104316.1, DERL1, TBC1D31, HMGB1P19, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1.
- chr8:123,352,181–123,470,028, 3 genes, copy number 6 (within-gene range 4–6): DUTP2, IMPDH1P6, NTAQ1.
- chr8:127,735,434–128,564,679, 14 genes, copy number 5: MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.
- chr8:140,657,900–141,195,808, 7 genes, copy number 6–13: PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1.
- chr8:143,857,324–145,066,685, 79 genes, copy number 6–11 (broad region; genes not listed).
- chr9:60,914,407–60,964,196, 5 genes, copy number 6: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.
- chr12:56,266,890–56,300,391, 3 genes, copy number 5 (within-gene range 2–5): COQ10A, AC073896.5, CS.
- chr14:105,583,731–105,588,395, 1 gene, copy number 5: IGHA2.

Autosomal genes at a single copy (total copy number 1): 4,609. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
